HCMI case HCM-EXPT-1047-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/3839c70c-c250-40af-a96a-4d5df8e3f700

Demographics
Sex at birth: male; Year of birth: 1956.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 63.8 years (23,291 days); Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRI.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRI.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin Calcium; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFIRI.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Leucovorin Calcium; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1047-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1047-C18-06A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1047-C18-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 15; Percent tumor nuclei: 25; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 85; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
